Somatic mutation profile of tumor specimen ALCH-AD0T-TTP1-A (aliquot ALCH-AD0T-TTP1-A-1-0-D-A509-36) from ALCHEMIST case ALCH-AD0T, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 52.6 years (19,204 days).
Specimen ALCH-AD0T-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb7587e5-07b9-484b-b830-2bcc2c3a9454.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AD0T-NB1-A (Blood Derived Normal), aliquot ALCH-AD0T-NB1-A-1-0-D-A509-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03d2b8dc-450d-4229-8969-c30f8731cafa

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 7, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCAF12L2 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1229366218, COSV63580270, COSV63581169; called by muse, mutect2
- DDX31 | c.733A>G p.I245V | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs756539611, COSV60136263; called by mutect2, varscan2
- ELAVL1 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as rs763270784, COSV60965768; called by muse, mutect2, varscan2
- GABRR2 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs754042657, COSV68765110, COSV68766312; called by muse, mutect2, varscan2
- MUS81 | c.58C>T p.L20F | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1391648979; called by muse, mutect2, varscan2
- PTPN14 | c.535C>A p.L179M | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65288138; called by muse, mutect2
- CCNB3 | c.2198A>C p.E733A | Missense Mutation (SNP) | VAF 31/256 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CSNK1E | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ITGAM | c.1285A>G p.I429V | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NECTIN1 | c.1236G>A p.M412I | Missense Mutation (SNP) | VAF 57/341 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR8J1 | c.85C>G p.L29V | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- PLAAT3 | c.321G>C p.K107N | Missense Mutation (SNP) | VAF 26/426 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.018); called by muse, mutect2
- PPM1E | c.1651G>C p.D551H | Missense Mutation (SNP) | VAF 36/242 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- THNSL1 | c.898A>G p.I300V | Missense Mutation (SNP) | VAF 13/289 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.069); called by muse, mutect2
- ZC3HC1 | c.1438A>G p.M480V | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2
- CCNB3 | c.2199G>A p.E733= | Silent (SNP) | VAF 30/253 reads (12%) | called by muse, mutect2, varscan2
- CXXC1 | c.114C>T p.C38= | Silent (SNP) | VAF 16/137 reads (12%) | catalogued as rs570978380; called by muse, mutect2, varscan2
- IFT81 | c.1935A>G p.L645= | Silent (SNP) | VAF 30/180 reads (17%) | called by muse, mutect2, varscan2
- KRT14 | c.138C>T p.Y46= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs565122423, COSV51421156; called by mutect2, varscan2
- TEKT4 | c.789G>A p.S263= | Silent (SNP) | VAF 16/158 reads (10%) | catalogued as rs201565255; called by muse, mutect2
- TMEM44 | c.1239C>T p.Y413= (on ENST00000392432 / NM_001166305.2; = p.Y366= on NM_138399.5) | Silent (SNP) | VAF 13/107 reads (12%) | called by muse, mutect2, varscan2
- ZNF14 | c.375C>T p.H125= | Silent (SNP) | VAF 30/276 reads (11%) | called by muse, mutect2, varscan2
- ITSN1 | c.2728-732G>A | Intron (SNP) | VAF 22/241 reads (9%) | called by muse, mutect2
